Surgical pathology report (de-identified scan), TCGA case TCGA-J8-A42S, project TCGA-THCA (Thyroid Carcinoma), tissue source site Mayo Clinic, specimen TCGA-J8-A42S-01A (Primary Tumor).

[page 1 of 3]
SurgPath Final
Temporary Copy

Case: [REDACTED]
Collected: [REDACTED]
Ordered by: [REDACTED]

Page 1 of 3

Patient: [REDACTED]
Location: [REDACTED]

FINAL DIAGNOSIS

- A) Thyroid, total thyroidectomy: Papillary thyroid carcinoma, forming two left lobe and one right lobe tumor masses, the largest 1.5 cm. Focal lymphovascular invasion is present. One (of one) lymph node is involved by metastatic papillary carcinoma with extranodal soft tissue involvement. Tumor invades into posterior left lobe capsule and is focally present at the inked surgical margin. (See Synoptic Report)
- B) Soft tissue, final posterior thyroid tumor margin: Benign fibroconnective tissue and small fragment of thyroid tissue. Negative for malignancy.

A: Thyroid Gland

HISTOLOGIC TYPE:

Papillary carcinoma
Classical (usual)

TUMOR FOCALITY:

Multifocal (specify):
Bilateral

ICD-O-3

Carcinoma, papillary, thyroid

8260/3

Site: thyroid, NOS

C73.9

TUMOR SIZE:

Greatest Dimension: 1.5 cm
Additional Dimensions: 0.5, 0.4 cm

8.3-12 cm

HISTOLOGIC GRADE

TNM DESCRIPTORS:

m (multiple primary tumors)

PRIMARY TUMOR (pT):

pT1b: Tumor more than 1 cm but not more than 2 cm in greatest dimension, limited to the thyroid

REGIONAL LYMPH NODES (pN):

pN1a: Nodal metastases to Level VI (pretracheal, paratracheal and prelaryngeal/Delphian) lymph nodes

NUMBER OF LYMPH NODE(S) INVOLVED: 1

NUMBER OF LYMPH NODE(S) EXAMINED: 1

LYMPH NODE, EXTRANODAL EXTENSION:

Present

[page 2 of 3]
MARGINS:

Margins uninvolved by carcinoma

LYMPH-VASCULAR INVASION:

Present:

Focal (less than 4 vessels)

PERINEURAL INVASION:

Not identified

EXTRATHYROIDAL EXTENSION:

Not identified

ADDITIONAL PATHOLOGIC FINDINGS:

Adenomatoid nodule(s) or Nodular follicular disease (eg, nodular hyperplasia, goitrous thyroid)

SPECIMEN RECEIVED

- A) TOTAL THYROID, STITCH MARKS LEFT UPPER LOBE, ASSESS POSTERIOR TUMOR MARGIN.
- B) POSTERIOR THYROID TUMOR MARGIN

FROZEN SECTION

- A) Representative section left lobe/isthmus nodule: Papillary thyroid carcinoma. Tumor abuts the capsule but inked margin is negative.

GROSS DESCRIPTION

A) Received fresh for frozen section labeled "total thyroid stitch marks left upper lobe" is a total thyroidectomy specimen weighing 16.5 gm, and measuring 6.5 x 5.0 x 1.5 cm. The red/tan capsular surface appears intact. The specimen is inked with black ink, serially sectioned and reveals a 1.5 cm in greatest dimension white/tan indurated lesion in the inferior aspect of the left lobe extending to the isthmus. On transection, this lesion focally abuts the inked surgical margin. Touch preps are made and a representative portion of the lesion is submitted for frozen section as A1. The remainder of the lesion is submitted for permanent section as A2 and A3.

[page 3 of 3]
Order # [REDACTED]

File # [REDACTED]
Location [REDACTED]

A second smaller nodule is identified in the inferior aspect of the left lobe measuring 0.3 cm in greatest dimension. This nodule grossly comes to within 0.3 cm of the inked surgical margin. A third smaller nodule is identified within the inferior aspect of right lower measuring 0.4 cm in greatest dimension. This nodule grossly comes within approximately 0.3 cm of the inked surgical margin. The remainder of the thyroid parenchyma displays beefy red/tan thyroid. A representative section of the tumor is submitted for the Thyroid Research Protocol. Additional sections are submitted for permanent section as follows: A4 nodule in the inferior aspect of the left lobe, A5 nodule in the inferior aspect of the right lobe, A6 representative section of left lobe, A7 representative section of the isthmus, A8 representative section of right lobe.

B) Received in formalin labeled "posterior thyroid tumor margin" is an irregular portion of red/tan soft tissue measuring 0.6 cm in greatest dimension. The specimen is entirely submitted in B1.

CLINICAL INFORMATION
RULE OUT THYROID CANCER

82/12

Source: NCI Genomic Data Commons file 47f3e2c8-5b7a-497c-b970-e2273fd272a6 (TCGA-J8-A42S.BB4E355B-3C6C-471E-8CF5-862CC0CD9935.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).